Gene-level copy-number profile of tumor specimen TCGA-R5-A7ZE-01B from TCGA case TCGA-R5-A7ZE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.6 years (24,328 days).
Specimen TCGA-R5-A7ZE-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f9371414-3c95-485d-a951-8a6b0302a7c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R5-A7ZE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d52a9e8-c720-482f-b57e-acf1a0b6510c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 445; copy number 2: 26,258; copy number 3: 15,391; copy number 4: 12,125; copy number 5: 4,527; copy number 6: 319; copy number 7: 224; copy number 8: 141; copy number 9: 122; copy number 10: 33; copy number 11: 13; copy number 14: 15; copy number 19: 16; copy number 20: 4; copy number 28: 60; copy number 32: 17; copy number 46: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R5-A7ZE-01B-11D-A34T-01): tumor purity 0.54, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr10:75,552,458–75,743,755, 4 genes: MIR606, AL589863.2, AL589863.1, AL731568.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,585 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,859,567–156,367,873, 31 genes, copy number 6 (within-gene range 4–6): SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3.
- chr1:234,527,887–235,097,412, 23 genes, copy number 6: LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1.
- chr2:8,461,703–8,684,461, 6 genes, copy number 6: LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2.
- chr2:27,889,941–30,408,346, 46 genes, copy number 5: BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1.
- chr2:100,271,875–100,996,829, 18 genes, copy number 5 (within-gene range 2–5): LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1.
- chr2:180,473,137–183,949,112, 45 genes, copy number 5: AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1.
- chr2:188,598,791–191,425,389, 53 genes, copy number 5–6: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr2:198,187,802–211,105,732, 270 genes, copy number 5–6 (broad region; genes not listed).
- chr2:211,777,206–212,426,360, 3 genes, copy number 5: MTND2P23, MTCO1P46, MIR548F2.
- chr3:79,957,566–81,297,345, 10 genes, copy number 14: HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1.
- chr3:81,840,514–84,947,061, 12 genes, copy number 10–20: AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr3:93,843,764–126,247,714, 502 genes, copy number 5–8 (broad region; genes not listed).
- chr3:160,227,454–175,810,548, 177 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr3:175,234,861–198,222,513, 495 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–1,613,897, 32 genes, copy number 5: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:2,227,803–23,649,774, 345 genes, copy number 5 (broad region; genes not listed).
- chr6:30,617,840–30,900,156, 24 genes, copy number 7 (within-gene range 4–7): MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640.
- chr7:70,972–260,772, 10 genes, copy number 6: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1.
- chr7:1,082,208–21,901,839, 306 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:24,132,705–27,212,965, 87 genes, copy number 5 (broad region; genes not listed).
- chr7:30,424,527–48,647,497, 328 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:48,846,426–55,713,252, 87 genes, copy number 5 (broad region; genes not listed).
- chr7:57,402,181–62,275,678, 30 genes, copy number 5: AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr8:100,380,486–145,066,685, 699 genes, copy number 5–10 (broad region; genes not listed).
- chr11:34,430,880–34,743,199, 8 genes, copy number 5: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1.
- chr13:73,112,915–73,661,891, 7 genes, copy number 6: RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr15:60,634,503–71,783,383, 249 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:80,769,600–80,951,776, 5 genes, copy number 5 (within-gene range 3–5): AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2.
- chr16:5,078,168–5,235,822, 7 genes, copy number 6: AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,632,566, 6 genes, copy number 6–9: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3, LINC01570, MIR8065.
- chr17:31,583,162–32,997,877, 59 genes, copy number 5: AC007923.3, AC007923.2, RNU6-1134P, GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:33,052,107–33,131,743, 3 genes, copy number 5: AC003687.1, AC008133.2, AC008133.1.
- chr17:39,637,090–41,930,542, 154 genes, copy number 28–46 (within-gene range 3–46) (broad region; genes not listed).
- chr17:62,910,021–68,797,822, 181 genes, copy number 5 (broad region; genes not listed).
- chr17:75,318,076–75,575,209, 13 genes, copy number 11 (within-gene range 4–11): GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2.
- chr19:29,205,320–30,909,155, 33 genes, copy number 19–32: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834.
- chr19:32,978,592–34,675,699, 51 genes, copy number 5–9 (within-gene range 2–9): RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P.
- chr20:49,794,811–64,313,132, 355 genes, copy number 5–6 (broad region; genes not listed).
- chr22:16,855,804–19,031,242, 97 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 445. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
